Somatic mutation profile of tumor specimen TCGA-S2-AA1A-01A (aliquot TCGA-S2-AA1A-01A-12D-A397-08) from TCGA case TCGA-S2-AA1A, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 68.2 years (24,903 days).
Specimen TCGA-S2-AA1A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eee3182-a4c8-4ccb-9894-547dd9a7111a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S2-AA1A-10A (Blood Derived Normal), aliquot TCGA-S2-AA1A-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c2f463b-28fd-44e5-94e4-a3562fdb221e

The open-access MAF lists 131 somatic variants for this specimen: 98 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 31, Nonsense Mutation 9, Frame Shift Del 3, Intron 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAD1 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99636121; called by muse, mutect2
- AP2A2 | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1179478553, COSV100173246; called by muse, mutect2
- ARHGEF6 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); catalogued as COSV99166649; called by muse, mutect2, varscan2
- ARMC7 | c.120del p.A41Pfs*85 | Frame Shift Del (DEL) | VAF 10/83 reads (12%) | catalogued as COSV55462348; called by mutect2, pindel, varscan2
- AUTS2 | c.3221C>T p.P1074L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV100719277; called by muse, mutect2, varscan2
- BMX | c.1580T>A p.L527* | Nonsense Mutation (SNP) | VAF 28/163 reads (17%) | catalogued as rs1486983136, COSV100564624, COSV59590439; called by muse, mutect2, varscan2
- C6orf118 | c.671A>T p.E224V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100024960; called by muse, mutect2, varscan2
- CASK | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.436); catalogued as COSV100587627; called by muse, mutect2
- CDH19 | c.2003G>C p.R668P | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs778502871, COSV100052086, COSV50961557; called by muse, mutect2, varscan2
- CDH3 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV99868965; called by muse, mutect2, varscan2
- CDH9 | c.928G>T p.G310* | Nonsense Mutation (SNP) | VAF 35/121 reads (29%) | catalogued as COSV50444912, COSV99151300; called by muse, mutect2, varscan2
- CHST1 | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100346474; called by muse, mutect2, varscan2
- CLSTN3 | c.1444C>A p.P482T | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.173); catalogued as COSV99867494; called by muse, mutect2, varscan2
- COIL | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.66); catalogued as COSV99538340; called by muse, mutect2, varscan2
- CRBN | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs768452189, COSV99214222; called by muse, mutect2, varscan2
- CRYBB2 | c.575A>T p.D192V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101236763; called by muse, mutect2, varscan2
- DEPDC1 | c.2259G>T p.R753S (on ENST00000456315 / NM_001114120.3; = p.R469S on NM_017779.6) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs913770247, COSV100920453; called by muse, mutect2, varscan2
- DNAH9 | c.2125T>C p.Y709H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99307565; called by muse, mutect2, varscan2
- DSG3 | c.2740G>A p.G914R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs1448395410, COSV99934616; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as COSV100349346; called by muse, mutect2, varscan2
- EPHA3 | c.1369T>A p.W457R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100347911; called by muse, mutect2, varscan2
- F13B | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV100803399; called by muse, mutect2, varscan2
- FBXO27 | c.406T>A p.W136R | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.083); catalogued as COSV99494735; called by muse, mutect2, varscan2
- FCGR2B | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99375342; called by muse, mutect2, varscan2
- FSHR | c.1952C>A p.A651D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100437823, COSV58630668; called by muse, mutect2, varscan2
- GPCPD1 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100980238; called by muse, mutect2
- GPRASP2 | c.675G>T p.W225C | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100176908; called by muse, mutect2, varscan2
- GRIN3A | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV100701731; called by muse, mutect2, varscan2
- GRM1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV99268441; called by muse, mutect2, varscan2
- GRPR | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100977689; called by muse, mutect2
- GUCY2F | c.1791+1G>T p.X597_splice | Splice Site (SNP) | VAF 20/240 reads (8%) | catalogued as COSV54307739, COSV99485519; called by muse, mutect2
- HSP90B1 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100236703; called by mutect2, varscan2
- HTR1F | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as rs1350414832, COSV100138168, COSV60390842; called by muse, mutect2
- IGSF22 | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100080250; called by muse, mutect2
- INPPL1 | c.2423C>G p.P808R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99996568; called by muse, mutect2, varscan2
- INTS6L | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.609); catalogued as COSV100878252; called by muse, mutect2
- IQGAP3 | c.1486G>T p.G496W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100752305; called by muse, mutect2, varscan2
- ITSN1 | c.5050G>T p.D1684Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV101182276; called by muse, mutect2, varscan2
- KCNF1 | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1437957849, COSV54462235, COSV99705842; called by muse, mutect2, varscan2
- KCNJ6 | c.808C>A p.R270S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV104384767, COSV99900321; called by muse, mutect2, varscan2
- KLK3 | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100386087; called by muse, mutect2, varscan2
- KRTAP4-12 | c.286T>G p.C96G | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV101224288; called by muse, varscan2
- LAIR1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV100479817; called by muse, mutect2, varscan2
- LTBP1 | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs747444314, COSV100617849; called by muse, mutect2, varscan2
- MAGEB10 | c.68A>T p.E23V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100775372; called by muse, mutect2, varscan2
- MAPT | c.1172C>T p.A391V (on ENST00000262410 / NM_001377265.1; = p.A316V on NM_016835.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs762447364, COSV99291179; called by muse, varscan2
- MRPL13 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 15/116 reads (13%) | catalogued as COSV100012480; called by muse, mutect2, varscan2
- MUC16 | c.40752C>A p.Y13584* | Nonsense Mutation (SNP) | VAF 32/226 reads (14%) | catalogued as rs1289342178, COSV101110043, COSV66696200; called by muse, mutect2, varscan2
- MUC16 | c.1910C>A p.S637Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV101201095; called by muse, mutect2, varscan2
- NFATC2 | c.2716G>C p.D906H | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101044100, COSV101044568; called by muse, mutect2, varscan2
- NFATC2 | c.2715G>T p.L905F | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101044570, COSV65354415; called by muse, mutect2, varscan2
- NOX1 | c.1561C>A p.H521N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV99471712; called by muse, mutect2, varscan2
- NR4A3 | c.1429C>A p.L477M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100432666, COSV58244311; called by muse, mutect2, varscan2
- NRIP1 | c.1615G>A p.V539M | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100013008; called by muse, mutect2, varscan2
- OR1F1 | c.601A>T p.S201C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100484490; called by muse, mutect2, varscan2
- OR2AK2 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.519); catalogued as COSV100824276; called by muse, mutect2, varscan2
- OR4K14 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100520504, COSV59292907; called by muse, mutect2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs747074822; called by mutect2, varscan2
- OR8H1 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV100477297, COSV57293377; called by muse, mutect2, varscan2
- OR8U1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100164078; called by muse, mutect2
- PCDHB16 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs1311553957, COSV53357820; called by muse, mutect2, varscan2
- PITPNC1 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100083998, COSV55458352; called by muse, mutect2, varscan2
- PKN3 | c.1147G>T p.V383L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.984); catalogued as rs781660120, COSV99403883; called by muse, mutect2, varscan2
- PLSCR5 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101494460; called by muse, mutect2, varscan2
- PNISR | c.2132T>A p.L711* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100984414; called by muse, mutect2, varscan2
- PNN | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV99397359; called by muse, mutect2, varscan2
- PRDM9 | c.53C>A p.T18K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV99691035; called by muse, mutect2, varscan2
- PROM1 | c.1543A>T p.I515F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV101477123; called by muse, mutect2, varscan2
- PSMB2 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs754270458, COSV100951569; called by muse, mutect2
- RABL3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV56337398, COSV99846630; called by muse, mutect2, varscan2
- RGS17 | c.576C>A p.N192K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.717); catalogued as COSV99243313; called by muse, mutect2, varscan2
- RSPO1 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as rs763148695, COSV100740681; called by muse, mutect2, varscan2
- SORCS1 | c.2051A>T p.H684L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV99549327; called by muse, mutect2, varscan2
- SPHK2 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as rs770765456, COSV99709540; called by mutect2, varscan2
- STKLD1 | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100912186; called by muse, mutect2, varscan2
- SYT10 | c.231G>T p.W77C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99951883; called by muse, mutect2, varscan2
- TAF1B | c.1516C>A p.L506M | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as COSV99722471; called by muse, mutect2
- TMPRSS11B | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs746441461, COSV100219485; called by muse, mutect2, varscan2
- TMTC3 | c.1758T>A p.Y586* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99898607; called by muse, mutect2
- TMTC3 | c.1760T>A p.L587H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.844); catalogued as COSV57122759, COSV99898609; called by muse, mutect2
- TNC | c.4395C>A p.F1465L | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs539803972, COSV100406132, COSV60788152; called by muse, mutect2, varscan2
- TNR | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV54902739, COSV99691045; called by muse, mutect2, varscan2
- TPK1 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.151); catalogued as COSV100766030; called by muse, mutect2, varscan2
- TRIM48 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV101338342, COSV101338398; called by muse, mutect2, varscan2
- TRIM48 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.328); catalogued as COSV101338324, COSV101338343; called by muse, mutect2, varscan2
- TRPA1 | c.1364G>T p.S455I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV100084324; called by muse, mutect2, varscan2
- TTYH1 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100002371; called by muse, mutect2, varscan2
- VNN3 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99258574; called by muse, mutect2, varscan2
- ZBTB49 | c.1211T>G p.F404C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100552556; called by muse, mutect2, varscan2
- ZFHX3 | c.8411C>G p.S2804C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99214267; called by muse, mutect2, varscan2
- ZFHX4 | c.1343C>A p.P448Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as rs747741880, COSV99266476; called by muse, mutect2, varscan2
- ZIC1 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51554081, COSV99292285; called by muse, mutect2, varscan2
- ZMYND8 | c.3164G>T p.W1055L (on ENST00000311275 / NM_001363741.2; = p.W1029L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99521153; called by muse, mutect2, varscan2
- ZNF718 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101210276; called by muse, mutect2, varscan2
- CYP2E1 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- NPR3 | c.1233_1236del p.R412Mfs*6 | Frame Shift Del (DEL) | VAF 22/152 reads (14%) | called by mutect2, pindel, varscan2
- OSBPL7 | c.1570A>C p.S524R | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SPATA31A1 | c.2926G>T p.D976Y | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ABCA5 | c.1239G>A p.L413= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as rs1293025666, COSV101201258; called by muse, mutect2, varscan2
- BIRC6 | c.10782T>C p.D3594= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV101428647; called by muse, mutect2, varscan2
- CCDC24 | c.333C>T p.S111= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV58842984; called by muse, mutect2
- CPB1 | c.888C>A p.S296= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99294464; called by muse, mutect2, varscan2
- DGKD | c.810C>T p.C270= (on ENST00000264057 / NM_152879.3; = p.C226= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs945377670, COSV99897295; called by muse, mutect2
- DMRTB1 | c.606T>C p.R202= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV101008392; called by muse, mutect2, varscan2
- ERC2 | c.609G>T p.R203= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99888443; called by muse, mutect2, varscan2
- FAM169A | c.1545C>A p.S515= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV100769097; called by muse, mutect2, varscan2
- FBN2 | c.3909T>A p.P1303= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV99330029; called by muse, mutect2, varscan2
- FBXO27 | c.405C>A p.G135= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV53072246, COSV99494738; called by muse, mutect2, varscan2
- GRIN2B | c.2583C>A p.V861= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV101662957; called by muse, mutect2, varscan2
- KDM5B | c.2787C>T p.D929= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs752648731, COSV99351231; called by muse, mutect2, varscan2
- KRT5 | c.507C>T p.R169= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as rs200658792, COSV52859976; called by muse, mutect2, varscan2
- LRRC28 | c.615A>G p.L205= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs781137940, COSV100113796; called by muse, mutect2, varscan2
- LRRC55 | c.561G>T p.G187= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV101546772, COSV73007106; called by muse, mutect2, varscan2
- MNDA | c.441A>G p.K147= | Silent (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- MUC16 | c.1911C>T p.S637= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs374207045, COSV101201319, COSV67495012; called by muse, mutect2, varscan2
- MYBPHL | c.615C>T p.I205= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs771724099, COSV100848875, COSV64063030; called by muse, mutect2, varscan2
- OR4K14 | c.240C>A p.P80= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV59294752; called by muse, mutect2
- OR51A2 | c.744A>C p.A248= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs1476938326, COSV100985082; called by muse, mutect2, varscan2
- RGS12 | c.1386G>T p.G462= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1464624622, COSV100374533; called by muse, mutect2, varscan2
- RTCA | c.804A>T p.V268= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99560098; called by muse, mutect2, varscan2
- SLC6A9 | c.1884C>A p.A628= (on ENST00000360584 / NM_201649.4; = p.A574= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100746474; called by muse, mutect2, varscan2
- SMG7 | c.2937C>T p.S979= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV100750523; called by muse, mutect2
- SMG8 | c.555A>G p.A185= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1310114001, COSV99959015; called by muse, mutect2, varscan2
- TMEM242 | c.21A>T p.A7= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as COSV100900972; called by muse, mutect2, varscan2
- TPR | c.5334C>T p.P1778= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV100824213; called by muse, mutect2, varscan2
- TRPV4 | c.2100G>T p.V700= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99924991; called by mutect2, varscan2
- VN1R4 | c.309C>A p.V103= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1432752321, COSV100237562; called by muse, mutect2, varscan2
- ZNF112 | c.1929G>T p.G643= (on ENST00000337401 / NM_001083335.2; = p.G637= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as COSV100496183; called by muse, mutect2, varscan2
- ZNF99 | c.1596T>A p.T532= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV101233919; called by muse, mutect2, varscan2
- CD300LD | chr17:74592711 C>T | 5'Flank (SNP) | VAF 7/40 reads (18%) | catalogued as rs1477097688; called by muse, mutect2, varscan2
- KIF1B | c.2115+7006C>T | Intron (SNP) | VAF 26/132 reads (20%) | catalogued as COSV99824021; called by muse, mutect2, varscan2
